Somatic mutation profile of tumor specimen TCGA-HZ-A9TJ-06A (aliquot TCGA-HZ-A9TJ-06A-11D-A40W-08) from TCGA case TCGA-HZ-A9TJ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 70.8 years (25,849 days).
Specimen TCGA-HZ-A9TJ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c331ab85-532b-4fd0-bb90-683fa46e6e88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A9TJ-10A (Blood Derived Normal), aliquot TCGA-HZ-A9TJ-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/160e573c-9a54-4242-bfc1-23443438d3c6

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, RNA 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 75/351 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 184/460 reads (40%) | catalogued as rs193922464, CM114804; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 98/227 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG8 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 140/449 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs202028007, COSV99699353; called by muse, mutect2, varscan2
- ADGRL4 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 98/620 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as rs1490356044, COSV66061144, COSV66066625; called by muse, mutect2, varscan2
- ALCAM | c.1717A>G p.K573E | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60254873; called by muse, mutect2, varscan2
- ALMS1 | c.10319G>A p.R3440K | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.089); catalogued as rs1412957434, COSV100043322; called by muse, mutect2
- BFSP2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 119/455 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100183843, COSV56591758; called by muse, mutect2, varscan2
- CADM2 | c.572G>A p.R191Q (on ENST00000407528 / NM_001167674.2; = p.R193Q on NM_153184.4) | Missense Mutation (SNP) | VAF 102/312 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs150681488; called by muse, mutect2, varscan2
- CELSR1 | c.1307C>G p.P436R | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53090885, COSV99416363; called by muse, mutect2, varscan2
- CELSR3 | c.6100A>T p.S2034C | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99374516; called by muse, mutect2, varscan2
- COL11A1 | c.3443C>G p.P1148R | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100614473; called by muse, mutect2, varscan2
- CUBN | c.10205C>T p.A3402V | Missense Mutation (SNP) | VAF 99/514 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.438); catalogued as rs758386041, COSV100911875; called by muse, mutect2, varscan2
- DLGAP2 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373082856; called by muse, mutect2, varscan2
- FAM120C | c.1019C>A p.A340E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100070364; called by muse, mutect2, varscan2
- FARP2 | c.29T>A p.V10D | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV99883604; called by muse, mutect2, varscan2
- FMNL3 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.736); catalogued as rs770930654, COSV53301070; called by muse, mutect2, varscan2
- GCN1 | c.6427G>A p.V2143I | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs115993320, COSV100325813; called by muse, mutect2, varscan2
- IRS1 | c.2569del p.R857Gfs*86 | Frame Shift Del (DEL) | VAF 58/409 reads (14%) | catalogued as COSV100524798; called by mutect2, pindel, varscan2
- KCNA1 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 198/1380 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as COSV101230084; called by muse, mutect2, varscan2
- L1CAM | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV100648817; called by muse, mutect2, varscan2
- LRRC7 | c.328C>T p.R110* (on ENST00000651989 / NM_001370785.2; = p.R77* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 102/527 reads (19%) | catalogued as COSV50415481, COSV50652183; called by muse, mutect2, varscan2
- LRRC7 | c.4444C>A p.P1482T (on ENST00000651989 / NM_001370785.2; = p.P1402T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.632); catalogued as COSV99223796; called by muse, mutect2, varscan2
- MYO5A | c.2099+1G>A p.X700_splice | Splice Site (SNP) | VAF 94/631 reads (15%) | catalogued as COSV100697188; called by muse, mutect2, varscan2
- OSBPL5 | c.701G>A p.W234* | Nonsense Mutation (SNP) | VAF 60/126 reads (48%) | catalogued as COSV99719866, COSV99720698; called by muse, mutect2, varscan2
- OTOF | c.4354C>T p.R1452C (on ENST00000272371 / NM_194248.3; = p.R685C on NM_004802.4) | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs560665036, COSV55510335; called by muse, mutect2, varscan2
- PDE3A | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV100761509; called by muse, mutect2, varscan2
- PEG3 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 145/1252 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99689974; called by muse, mutect2, varscan2
- PFKFB4 | c.1031A>T p.Y344F | Missense Mutation (SNP) | VAF 41/165 reads (25%) | PolyPhen benign (0.013); catalogued as COSV99219247; called by muse, mutect2, varscan2
- PIWIL1 | c.1032A>C p.E344D | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99806777; called by muse, mutect2, varscan2
- PLEKHH2 | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 196/640 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1310606168, COSV99174258; called by muse, mutect2, varscan2
- PRR12 | c.2663C>T p.T888M (on ENST00000615927; = p.T1709M on NM_020719.3) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1005415110, COSV101330760; called by muse, mutect2
- PRR5L | c.641T>A p.V214E | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100286750; called by muse, mutect2, varscan2
- RBM27 | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99505545; called by muse, mutect2, varscan2
- SLC12A5 | c.3192C>T p.N1064= (on ENST00000454036 / NM_001134771.2; = p.N1041= on NM_020708.5) | Splice Region (SNP) | VAF 68/536 reads (13%) | catalogued as COSV99275080; called by muse, mutect2, varscan2
- SLC9A9 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 210/944 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs775249012, COSV57216495; called by muse, mutect2, varscan2
- TDG | c.724G>T p.V242F | Missense Mutation (SNP) | VAF 22/654 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV99903945; called by muse, mutect2
- TEX19 | c.439T>C p.W147R | Missense Mutation (SNP) | VAF 89/499 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100330968; called by muse, mutect2, varscan2
- TGS1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 98/542 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV99485612, COSV99485818; called by muse, mutect2, varscan2
- THSD7B | c.3809G>A p.R1270Q (on ENST00000272643; = p.R1268Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 204/600 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as rs750716218, COSV55711536; called by muse, mutect2, varscan2
- TIAM1 | c.4400C>T p.P1467L | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs201116117, COSV54542314; called by muse, mutect2, varscan2
- TIAM1 | c.2090G>T p.W697L | Missense Mutation (SNP) | VAF 112/568 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as COSV99731932; called by muse, mutect2, varscan2
- TTN | c.98876G>A p.W32959* (on ENST00000591111; = p.W25535* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 83/271 reads (31%) | catalogued as COSV100589455; called by muse, mutect2, varscan2
- UBA7 | c.2921T>A p.L974Q | Missense Mutation (SNP) | VAF 114/206 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100323455; called by muse, mutect2, varscan2
- VPS13D | c.6281C>T p.T2094M | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs867243077, COSV50625950; called by muse, mutect2, varscan2
- FOXD4L4 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 115/816 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF1A | c.2108_2119del p.E703_L706del | In Frame Del (DEL) | VAF 32/196 reads (16%) | called by mutect2, pindel
- TFAP2C | c.1139_1140del p.P380Rfs*57 | Frame Shift Del (DEL) | VAF 130/516 reads (25%) | called by mutect2, pindel, varscan2
- WTAP | c.145+2dup p.X49_splice | Splice Site (INS) | VAF 53/291 reads (18%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.1983G>A p.V661= | Silent (SNP) | VAF 328/575 reads (57%) | catalogued as COSV99893568; called by muse, mutect2, varscan2
- COL4A2 | c.1209G>A p.P403= | Silent (SNP) | VAF 155/447 reads (35%) | catalogued as rs775959840, COSV64625609, COSV64628387; called by muse, mutect2, varscan2
- DNAH11 | c.699G>A p.P233= | Silent (SNP) | VAF 28/241 reads (12%) | catalogued as rs373971291; ClinVar: likely benign; called by muse, mutect2, varscan2
- EML1 | c.2211G>A p.S737= | Silent (SNP) | VAF 86/381 reads (23%) | catalogued as rs553895497, COSV51748824; called by muse, mutect2, varscan2
- GRIA1 | c.330G>A p.T110= | Silent (SNP) | VAF 123/487 reads (25%) | catalogued as rs370782311, COSV53588479; called by muse, mutect2, varscan2
- KIAA1210 | c.18G>T p.T6= | Silent (SNP) | VAF 133/232 reads (57%) | catalogued as COSV68180330, COSV68180653; called by muse, mutect2, varscan2
- LSS | c.2064G>A p.P688= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as rs774062012, COSV62700436; called by mutect2, varscan2
- MRPL57 | c.78C>T p.F26= | Silent (SNP) | VAF 54/405 reads (13%) | catalogued as COSV100006050; called by muse, mutect2, varscan2
- NCKAP5 | c.3603C>T p.I1201= | Silent (SNP) | VAF 41/340 reads (12%) | catalogued as COSV100489435; called by muse, mutect2, varscan2
- NELL1 | c.1749C>T p.D583= | Silent (SNP) | VAF 90/398 reads (23%) | catalogued as rs758011669, COSV100117908; called by muse, mutect2, varscan2
- OR2M4 | c.825G>A p.S275= | Silent (SNP) | VAF 70/496 reads (14%) | catalogued as rs1399023386, COSV100140911; called by muse, mutect2, varscan2
- PCDH11X | c.1410C>T p.F470= | Silent (SNP) | VAF 182/283 reads (64%) | catalogued as rs768670963, COSV100007108; called by muse, mutect2, varscan2
- PRRC2C | c.3132C>T p.V1044= (on ENST00000367742; = p.V1042= on NM_015172.4) | Silent (SNP) | VAF 160/402 reads (40%) | catalogued as COSV100144492; called by muse, mutect2, varscan2
- PTPN21 | c.85C>T p.L29= | Silent (SNP) | VAF 93/464 reads (20%) | catalogued as COSV100161345, COSV60850122; called by muse, mutect2, varscan2
- ZSCAN10 | c.885G>A p.A295= (on ENST00000252463; = p.A350= on NM_032805.3) | Silent (SNP) | VAF 100/477 reads (21%) | catalogued as rs773862495, COSV99373749; called by muse, mutect2, varscan2
- KIR3DX1 | n.864C>T | RNA (SNP) | VAF 186/846 reads (22%) | catalogued as rs760842823, COSV55597926; called by muse, mutect2, varscan2
- MIR520H | n.55dup | RNA (INS) | VAF 92/741 reads (12%) | catalogued as rs1241973472; called by mutect2, varscan2
